FM case AD14591 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/2c48398a-031a-4475-8334-85fe04d488e6

Female, 52.1 years: Follicular carcinoma, NOS (ICD-O-3 8330/3) of the thyroid gland; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
